Somatic mutation profile of tumor specimen ALCH-B43B-TTP1-A (aliquot ALCH-B43B-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B43B, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 83.7 years (30,560 days).
Specimen ALCH-B43B-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af7df6a2-5d4e-4dc3-a90d-7d508acf425e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B43B-NB1-A (Blood Derived Normal), aliquot ALCH-B43B-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28d649f2-1084-420f-8af3-ca6e8b0dac77

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 5/51 reads (10%) | catalogued as rs754135731; called by mutect2, varscan2*
- NT5C3A | c.*364T>C | 3'UTR (SNP) | VAF 18/152 reads (12%) | catalogued as rs1465588296; called by muse, mutect2
